Somatic mutation profile of tumor specimen TCGA-G2-A2EL-01A (aliquot TCGA-G2-A2EL-01A-12D-A18F-08) from TCGA case TCGA-G2-A2EL, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 77.7 years (28,370 days).
Specimen TCGA-G2-A2EL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 228023b1-ce36-481f-abbe-c630276125ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G2-A2EL-10A (Blood Derived Normal), aliquot TCGA-G2-A2EL-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d8ef91f7-ae8a-42f0-afe6-3c92a7cb1c4f

The open-access MAF lists 262 somatic variants for this specimen: 177 protein-altering or splice-affecting, 74 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 147, Silent 74, Nonsense Mutation 22, Splice Site 6, Intron 5, 5'Flank 3, 5'UTR 2, 3'Flank 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA1 | c.3841C>T p.Q1281* | Nonsense Mutation (SNP) | VAF 70/157 reads (45%) | catalogued as rs80356866, CM960180, COSV100525178; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.4505G>A p.W1502* | Nonsense Mutation (SNP) | VAF 106/114 reads (93%) | hotspot (GDC flag); catalogued as COSV52116160, COSV99272247; called by muse, mutect2, varscan2
- EP300 | c.4365G>C p.Q1455H | Missense Mutation (SNP) | VAF 39/87 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54326253, COSV54333390, COSV54337016; called by muse, mutect2, varscan2
- KDM6A | c.1663C>T p.Q555* | Nonsense Mutation (SNP) | VAF 27/27 reads (100%) | hotspot (GDC flag); catalogued as COSV65037942; called by muse, mutect2, varscan2
- PTEN | c.733C>T p.Q245* | Nonsense Mutation (SNP) | VAF 37/40 reads (93%) | catalogued as rs786202918, CM981673, COSV100910801, COSV64288504; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.2548C>T p.Q850* | Nonsense Mutation (SNP) | VAF 41/41 reads (100%) | catalogued as rs886042935, COSV57296102; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1101-2A>G p.X367_splice | Splice Site (SNP) | VAF 59/61 reads (97%) | catalogued as rs587781664, CS111031, COSV52676811, COSV52714663, COSV53348267; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AATK | c.3026C>G p.S1009* (on ENST00000326724 / NM_001080395.3; = p.S906* on NM_004920.2) | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as rs1386070653, COSV100353276; called by muse, mutect2, varscan2
- AATK | c.2510C>T p.A837V (on ENST00000326724 / NM_001080395.3; = p.A734V on NM_004920.2) | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs372570290; called by muse, mutect2, varscan2
- AATK | c.1838C>T p.S613L (on ENST00000326724 / NM_001080395.3; = p.S510L on NM_004920.2) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs753408863, COSV58366168; called by muse, mutect2, varscan2
- ABCA13 | c.3395C>G p.S1132* | Nonsense Mutation (SNP) | VAF 29/61 reads (48%) | catalogued as rs750034315, COSV101330194, COSV70042293; called by muse, mutect2
- ABCC3 | c.3964G>A p.V1322M | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs142763506; called by muse, mutect2, varscan2
- ABCC5 | c.4174C>G p.L1392V | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.233); catalogued as COSV55587169, COSV55590533; called by muse, mutect2, varscan2
- ABCC9 | c.163A>G p.K55E | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.826); catalogued as COSV53973048; called by muse, mutect2, varscan2
- ADGRA2 | c.2029C>T p.P677S | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100178445; called by muse, mutect2
- ADGRB3 | c.4504G>C p.E1502Q | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV53245945, COSV99484953; called by muse, mutect2, varscan2
- ALDH16A1 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.267); catalogued as rs781770831, COSV53192575; called by muse, mutect2, varscan2
- ANKRD12 | c.5210G>C p.R1737T | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV50826117; called by muse, mutect2, varscan2
- APOBEC3D | c.1123C>T p.R375* | Nonsense Mutation (SNP) | VAF 63/132 reads (48%) | catalogued as rs765057107, COSV53325807; called by muse, mutect2, varscan2
- ARHGAP31 | c.645C>G p.I215M | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV51792459, COSV51793313; called by muse, mutect2, varscan2
- ARHGAP45 | c.2641G>A p.E881K | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.753); catalogued as COSV57432378; called by muse, mutect2, varscan2
- ARID1A | c.1901C>G p.S634* | Nonsense Mutation (SNP) | VAF 60/62 reads (97%) | catalogued as COSV61385759; called by muse, mutect2, varscan2
- ARID4A | c.1970G>C p.R657T | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV62163936; called by muse, mutect2, varscan2
- BDP1 | c.275C>G p.S92* | Nonsense Mutation (SNP) | VAF 60/120 reads (50%) | catalogued as COSV100703572, COSV62434644; called by muse, mutect2, varscan2
- BRAF | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.125); catalogued as COSV56191665; called by muse, varscan2
- CARM1 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV59000435; called by muse, mutect2, varscan2
- CCDC88C | c.2343G>C p.K781N | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1396545620, COSV66238369; called by muse, mutect2, varscan2
- CCRL2 | c.431G>C p.R144T | Missense Mutation (SNP) | VAF 45/48 reads (94%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62193529; called by muse, mutect2, varscan2
- CD28 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 71/74 reads (96%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV60730744; called by muse, mutect2, varscan2
- CDC42BPA | c.4698G>T p.M1566I (on ENST00000334218 / NM_001366019.2; = p.M1553I on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV62011553, COSV62014460, COSV62021326; called by muse, mutect2, varscan2
- CDH3 | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 60/108 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as COSV50558641; called by muse, mutect2, varscan2
- CHML | c.437C>T p.S146L | Missense Mutation (SNP) | VAF 77/183 reads (42%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs959795086, COSV59364484; called by muse, mutect2, varscan2
- CLCN1 | c.1548C>G p.I516M | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV58370244; called by muse, mutect2, varscan2
- CNST | c.1245G>C p.E415D | Missense Mutation (SNP) | VAF 114/244 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs745356529, COSV63621832; called by muse, mutect2, varscan2
- CNST | c.1368G>C p.Q456H | Missense Mutation (SNP) | VAF 91/211 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV63621835; called by muse, mutect2, varscan2
- COL17A1 | c.416-1G>C p.X139_splice | Splice Site (SNP) | VAF 24/62 reads (39%) | catalogued as rs771751027, COSV62226955; called by muse, mutect2, varscan2
- COL5A3 | c.1683G>C p.E561D | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.034); catalogued as COSV53411318, COSV53412750; called by muse, mutect2, varscan2
- CORIN | c.2042C>A p.S681* | Nonsense Mutation (SNP) | VAF 24/62 reads (39%) | catalogued as COSV99902810; called by muse, mutect2, varscan2
- CREB3L4 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 64/106 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0.193); catalogued as COSV55132173; called by muse, mutect2, varscan2
- CTNNA2 | c.1514C>T p.S505L | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV58143442, COSV58154065; called by muse, mutect2, varscan2
- CYP26B1 | c.1384A>G p.S462G | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV50011964; called by muse, mutect2, varscan2
- CYP2B6 | c.606C>G p.F202L | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT tolerated (0.81); PolyPhen benign (0.045); catalogued as COSV57843833; called by muse, mutect2, varscan2
- DCC | c.846C>G p.L282= | Splice Region (SNP) | VAF 27/50 reads (54%) | catalogued as rs1232175532, COSV59104421; called by muse, mutect2
- DLG1 | c.2523G>C p.M841I (on ENST00000419354 / NM_001290983.1; = p.M863I on NM_004087.2) | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.135); catalogued as COSV58383414, COSV58386631; called by muse, mutect2, varscan2
- DNAH11 | c.10351G>A p.E3451K | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs765933686, COSV60957408; called by muse, mutect2
- DTX3L | c.1772C>T p.S591L | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV56144266; called by muse, mutect2, varscan2
- EIF4G1 | c.428G>A p.G143D | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100072336; called by muse, mutect2, varscan2
- EMC7 | c.425C>G p.S142C | Missense Mutation (SNP) | VAF 31/33 reads (94%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV104374698, COSV56627917; called by muse, mutect2, varscan2
- EPC2 | c.728G>C p.R243T | Missense Mutation (SNP) | VAF 20/20 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV51544318; called by muse, mutect2, varscan2
- EXOSC10 | c.111+1G>C p.X37_splice | Splice Site (SNP) | VAF 22/65 reads (34%) | catalogued as COSV58665571; called by muse, mutect2, varscan2
- F2RL2 | c.474C>A p.N158K | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs765431749, COSV56970780; called by muse, mutect2, varscan2
- FAM184A | c.2048G>C p.R683T | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV58854682; called by muse, mutect2, varscan2
- FILIP1L | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58769373; called by muse, mutect2, varscan2
- GAS2L1 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.811); catalogued as rs766729816, COSV53330574; called by muse, varscan2
- GEMIN2 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs550635715, COSV51628176; called by muse, mutect2, varscan2
- GLCE | c.871G>C p.D291H | Missense Mutation (SNP) | VAF 24/25 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55946021; called by muse, mutect2, varscan2
- GPR18 | c.207G>C p.L69F | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV61621239; called by muse, mutect2, varscan2
- GPR85 | c.261G>A p.W87* | Nonsense Mutation (SNP) | VAF 27/71 reads (38%) | catalogued as COSV99775305; called by muse, mutect2, varscan2
- GRIK4 | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.41); catalogued as COSV70801190, COSV70802525; called by muse, mutect2, varscan2
- GTF3C1 | c.849+1G>T p.X283_splice | Splice Site (SNP) | VAF 23/58 reads (40%) | catalogued as COSV62241528; called by muse, mutect2, varscan2
- GTF3C1 | c.87G>C p.E29D | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.702); catalogued as COSV55181347; called by muse, mutect2, varscan2
- H2AC14 | c.89G>T p.R30L | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100297656, COSV60798844; called by muse, mutect2
- H3C3 | c.49C>G p.P17A | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.159); catalogued as COSV63551010; called by muse, mutect2, varscan2
- HELQ | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 92/201 reads (46%) | catalogued as COSV99788182; called by muse, mutect2, varscan2
- HINFP | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV63432052; called by muse, mutect2, varscan2
- HIVEP3 | c.1555G>C p.E519Q | Missense Mutation (SNP) | VAF 55/197 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.906); catalogued as COSV56015913; called by muse, mutect2, varscan2
- HMBOX1 | c.906C>G p.N302K | Missense Mutation (SNP) | VAF 67/129 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV55066819, COSV55068351; called by muse, mutect2, varscan2
- HOXC6 | c.348G>C p.Q116H | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV54536980; called by muse, mutect2, varscan2
- HSPA2 | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.936); catalogued as COSV55969736; called by muse, mutect2, varscan2
- IL17RA | c.1886C>G p.S629C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV100083474; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1727G>C p.S576T | Missense Mutation (SNP) | VAF 29/29 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.4); catalogued as COSV56263602; called by muse, mutect2, varscan2
- ING3 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 76/139 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs769127768, COSV59242502; called by muse, mutect2, varscan2
- JADE1 | c.956A>G p.N319S | Missense Mutation (SNP) | VAF 119/126 reads (94%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as rs1416545822, COSV56906169; called by muse, mutect2, varscan2
- KCNK1 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.061); catalogued as COSV64038323; called by muse, varscan2
- KHDC4 | c.1111C>T p.Q371* | Nonsense Mutation (SNP) | VAF 36/75 reads (48%) | catalogued as rs909402391, COSV100850859; called by muse, mutect2, varscan2
- KMT2D | c.9543G>C p.E3181D | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.013); catalogued as COSV56443455, COSV56457031; called by muse, mutect2, varscan2
- KMT2D | c.9016G>A p.D3006N | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV56443473; called by muse, mutect2, varscan2
- LIMA1 | c.84G>T p.K28N | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100372191, COSV57965646; called by muse, mutect2, varscan2
- LOX | c.1229C>G p.S410* | Nonsense Mutation (SNP) | VAF 48/122 reads (39%) | catalogued as COSV99140733; called by muse, mutect2, varscan2
- LRRC7 | c.1420G>A p.D474N (on ENST00000651989 / NM_001370785.2; = p.D441N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.411); catalogued as COSV50465541; called by muse, mutect2, varscan2
- LRRIQ1 | c.433A>G p.M145V | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1250249366, COSV67813110; called by muse, mutect2, varscan2
- MAP3K2 | c.992G>A p.S331N | Missense Mutation (SNP) | VAF 18/18 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.238); catalogued as COSV61294490; called by muse, mutect2, varscan2
- MCOLN1 | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.511); catalogued as COSV51175930; called by muse, mutect2, varscan2
- MIA2 | c.1577C>G p.S526C | Missense Mutation (SNP) | VAF 45/91 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV54483703; called by muse, mutect2, varscan2
- MIA2 | c.1168C>G p.Q390E | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.155); catalogued as COSV54493825; called by muse, mutect2, varscan2
- MR1 | c.702G>C p.M234I | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV51580892; called by muse, mutect2, varscan2
- MYO16 | c.3140C>G p.S1047* | Nonsense Mutation (SNP) | VAF 26/99 reads (26%) | catalogued as COSV100697418, COSV62760038; called by muse, mutect2, varscan2
- NCAPD3 | c.1325A>G p.K442R | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as COSV73258404; called by muse, mutect2, varscan2
- NFATC3 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as COSV60474021; called by muse, mutect2, varscan2
- NFX1 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.477); catalogued as COSV59310442; called by muse, mutect2, varscan2
- NHLRC2 | c.1871C>A p.S624* | Nonsense Mutation (SNP) | VAF 41/90 reads (46%) | catalogued as COSV100993034; called by muse, mutect2, varscan2
- NLRP14 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.036); catalogued as COSV55067575; called by muse, varscan2
- NLRP14 | c.2497G>A p.E833K | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.132); catalogued as COSV55067596; called by muse, mutect2, varscan2
- NPR2 | c.1251G>C p.Q417H | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.332); catalogued as COSV61311053; called by muse, mutect2, varscan2
- NPR2 | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.065); catalogued as COSV61311069; called by muse, mutect2, varscan2
- NPR2 | c.1675G>C p.E559Q | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV61311083; called by muse, mutect2, varscan2
- NSD1 | c.3388G>C p.E1130Q | Missense Mutation (SNP) | VAF 15/15 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV61776767; called by muse, mutect2, varscan2
- NUDT7 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.034); catalogued as rs1456507486, COSV51745527; called by muse, mutect2, varscan2
- NWD1 | c.3830G>A p.G1277E | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1163756950, COSV60343130; called by muse, mutect2, varscan2
- OR4D11 | c.906G>C p.K302N | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV57585725, COSV57585770; called by muse, mutect2, varscan2
- OR4K2 | c.240G>C p.K80N | Missense Mutation (SNP) | VAF 61/243 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV100064012, COSV53849078, COSV53849409; called by muse, mutect2, varscan2
- OR51I2 | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773003890, COSV58298846; called by muse, mutect2, varscan2
- PAN2 | c.697G>C p.D233H | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as COSV57754076; called by muse, mutect2, varscan2
- PCDHA7 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); catalogued as COSV100971868; called by muse, varscan2
- PCDHB1 | c.2413C>G p.Q805E | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV60631168; called by muse, mutect2, varscan2
- PCDHGA1 | c.905C>G p.S302* | Nonsense Mutation (SNP) | VAF 19/45 reads (42%) | catalogued as rs1285679219, COSV100966123, COSV65297246; called by muse, mutect2, varscan2
- PDE4A | c.1720G>C p.D574H (on ENST00000380702 / NM_001111307.2; = p.D335H on NM_006202.3) | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53356464; called by muse, mutect2, varscan2
- PLCL2 | c.1063A>G p.K355E (on ENST00000615277 / NM_001144382.2; = p.K229E on NM_015184.5) | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV67622330; called by muse, mutect2, varscan2
- PLEKHG2 | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.372); catalogued as rs985795212, COSV52683978; called by muse, mutect2, varscan2
- POLQ | c.6175C>G p.Q2059E | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.97); catalogued as COSV51752665; called by muse, mutect2, varscan2
- PROX2 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.533); catalogued as rs768044735, COSV71519982; called by muse, mutect2, varscan2
- PRSS12 | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 42/45 reads (93%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV56606627; called by muse, mutect2, varscan2
- PTPRO | c.1106-1G>C p.X369_splice | Splice Site (SNP) | VAF 7/27 reads (26%) | catalogued as COSV55510986, COSV55524301, COSV99841710; called by muse, mutect2, varscan2
- RABGEF1 | c.835G>C p.D279H (on ENST00000439720 / NM_001287061.2; = p.D266H on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.858); catalogued as COSV53162482; called by muse, mutect2, varscan2
- RCCD1 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 40/42 reads (95%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs769774952, COSV62695425; called by muse, mutect2, varscan2
- RECK | c.1935G>C p.Q645H | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV65035465; called by muse, mutect2, varscan2
- RIMS2 | c.4342G>T p.D1448Y (on ENST00000666250 / NM_001348490.2; = p.D1019Y on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.989); catalogued as COSV51684711; called by muse, mutect2, varscan2
- RNF214 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); catalogued as rs373008488; called by muse, varscan2
- RRH | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 37/40 reads (93%) | SIFT deleterious (0.05); PolyPhen benign (0.403); catalogued as COSV58491421; called by muse, mutect2, varscan2
- RTTN | c.191T>G p.V64G | Missense Mutation (SNP) | VAF 82/150 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55345267; called by muse, mutect2, varscan2
- SCAP | c.1765G>A p.E589K | Missense Mutation (SNP) | VAF 57/62 reads (92%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV55561688, COSV99652924; called by muse, mutect2, varscan2
- SCN3A | c.3511G>A p.E1171K | Missense Mutation (SNP) | VAF 37/38 reads (97%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV51810880; called by muse, mutect2, varscan2
- SCNN1A | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); catalogued as rs1262766728, COSV57435805; called by muse, mutect2
- SEC63 | c.1463C>G p.S488C | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV64599942; called by muse, mutect2, varscan2
- SEPTIN8 | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 98/201 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs751928524, COSV51524033; called by muse, mutect2, varscan2
- SETD6 | c.709G>C p.E237Q (on ENST00000219315 / NM_001160305.4; = p.E213Q on NM_024860.3) | Missense Mutation (SNP) | VAF 71/185 reads (38%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.575); catalogued as COSV50748028; called by muse, mutect2, varscan2
- SETD6 | c.1186G>A p.E396K (on ENST00000219315 / NM_001160305.4; = p.E372K on NM_024860.3) | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.416); catalogued as COSV54700223; called by muse, mutect2, varscan2
- SH3GLB2 | c.377G>C p.G126A | Missense Mutation (SNP) | VAF 68/72 reads (94%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as COSV65330993; called by muse, mutect2, varscan2
- SIGLEC7 | c.470C>A p.T157N | Missense Mutation (SNP) | VAF 98/237 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV58315967; called by muse, mutect2, varscan2
- SLC26A1 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.292); catalogued as rs979982412, COSV68310368, COSV68311743; called by muse, mutect2, varscan2
- SLC4A10 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 45/55 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV55780444; called by muse, mutect2, varscan2
- SMOX | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.967); catalogued as COSV53865169; called by muse, mutect2, varscan2
- SNAP25 | c.572G>C p.R191T | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV54772479; called by muse, mutect2, varscan2
- STT3A | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 88/202 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); catalogued as COSV67064784; called by muse, mutect2, varscan2
- SUPT16H | c.1421G>A p.R474Q | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs756418970, COSV53525239; called by muse, mutect2, varscan2
- SYBU | c.452C>T p.S151L (on ENST00000276646 / NM_001099754.2; = p.S150L on NM_017786.6) | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760472725, COSV52618447, COSV52623808; called by muse, mutect2, varscan2
- SYNE2 | c.7366G>C p.E2456Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as COSV59952086; called by muse, mutect2, varscan2
- TAS1R3 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.846); catalogued as rs752556341, COSV59563597; called by muse, mutect2, varscan2
- TAS1R3 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.475); catalogued as COSV59563612; called by muse, varscan2
- TAS1R3 | c.2149G>A p.E717K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as rs1174026670, COSV100229565; called by muse, mutect2
- TGFBR3 | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53025813; called by muse, mutect2, varscan2
- THSD7B | c.4340G>A p.R1447Q (on ENST00000272643; = p.R1445Q on NM_001316349.2) | Missense Mutation (SNP) | VAF 27/29 reads (93%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs267598902, COSV55651965; called by muse, mutect2, varscan2
- TINAGL1 | c.1131G>C p.K377N | Missense Mutation (SNP) | VAF 38/50 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV54699139; called by muse, mutect2, varscan2
- TMEM213 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | catalogued as COSV100023723; called by muse, mutect2, varscan2
- TMEM61 | c.351G>C p.E117D | Missense Mutation (SNP) | VAF 126/189 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV64873587; called by muse, mutect2, varscan2
- TNN | c.1861G>C p.D621H | Missense Mutation (SNP) | VAF 89/189 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53426892; called by muse, mutect2, varscan2
- TNN | c.2047G>T p.E683* | Nonsense Mutation (SNP) | VAF 35/79 reads (44%) | catalogued as rs1204656551, COSV53431283; called by muse, mutect2, varscan2
- TPR | c.23T>A p.V8D | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV55217060; called by muse, mutect2, varscan2
- TRAF3IP3 | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV50553473; called by muse, mutect2, varscan2
- TRIM62 | c.51C>G p.I17M | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV52221475; called by muse, mutect2, varscan2
- TRPS1 | c.1124C>T p.S375L (on ENST00000220888 / NM_001330599.2; = p.S388L on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.344); catalogued as COSV55241670; called by muse, mutect2, varscan2
- TSTD2 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 44/45 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747590769, COSV57846032; called by muse, mutect2, varscan2
- TTC17 | c.2831C>G p.A944G | Missense Mutation (SNP) | VAF 62/125 reads (50%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV50008896; called by muse, mutect2, varscan2
- TTC39A | c.962C>G p.A321G (on ENST00000447632 / NM_001297665.1; = p.A286G on NM_001080494.3) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV52958315; called by muse, mutect2, varscan2
- TTLL4 | c.1951C>T p.R651* | Nonsense Mutation (SNP) | VAF 66/73 reads (90%) | catalogued as rs1407008594, COSV99293787; called by muse, mutect2, varscan2
- TTN | c.89203T>C p.Y29735H (on ENST00000591111; = p.Y22311H on NM_003319.4) | Missense Mutation (SNP) | VAF 12/12 reads (100%) | PolyPhen probably damaging (0.998); catalogued as rs1434130834, COSV60087540; called by mutect2, varscan2
- TUBGCP2 | c.731G>T p.R244L | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV53303048; called by muse, mutect2
- TUBGCP6 | c.4414G>C p.V1472L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV50547317; called by muse, mutect2, varscan2
- TXNDC5 | c.1177G>A p.V393I | Missense Mutation (SNP) | VAF 32/70 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.123); catalogued as COSV51665872; called by muse, mutect2, varscan2
- USF3 | c.4231C>G p.P1411A | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.48); catalogued as COSV57073136; called by muse, mutect2, varscan2
- USP13 | c.1380+1G>A p.X460_splice | Splice Site (SNP) | VAF 31/79 reads (39%) | catalogued as COSV55865961; called by muse, mutect2, varscan2
- USP15 | c.1188G>C p.L396F (on ENST00000280377 / NM_001351159.2; = p.L367F on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54792656; called by muse, mutect2, varscan2
- USP3 | c.1181C>A p.S394Y | Missense Mutation (SNP) | VAF 29/32 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51427648; called by muse, mutect2, varscan2
- VPS33A | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV57357140; called by muse, mutect2, varscan2
- VSX2 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56217473; called by muse, mutect2, varscan2
- WDFY3 | c.5971G>C p.E1991Q | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV55701946; called by muse, mutect2, varscan2
- ZFYVE9 | c.4243G>C p.E1415Q | Missense Mutation (SNP) | VAF 53/155 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55094212; called by muse, mutect2, varscan2
- ZIC1 | c.152C>A p.P51H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV51553879; called by muse, mutect2, varscan2
- ZKSCAN4 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.06); catalogued as COSV66023351; called by muse, mutect2, varscan2
- ZNF14 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as COSV59849723; called by muse, mutect2, varscan2
- ZNF335 | c.3628G>C p.D1210H | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59818008, COSV59818905; called by muse, mutect2, varscan2
- ZNF337 | c.576G>C p.K192N | Missense Mutation (SNP) | VAF 82/158 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.514); catalogued as COSV53321540; called by muse, mutect2, varscan2
- ZNF37A | c.279C>G p.F93L | Missense Mutation (SNP) | VAF 52/56 reads (93%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV61073767; called by muse, mutect2, varscan2
- ZNF615 | c.262C>G p.L88V | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs964751746, COSV65033481; called by muse, mutect2, varscan2
- ZSCAN22 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61639145; called by muse, mutect2, varscan2
- ZWILCH | c.1361C>G p.S454* | Nonsense Mutation (SNP) | VAF 30/32 reads (94%) | catalogued as COSV100328973; called by muse, mutect2, varscan2
- DDX28 | c.384del p.F128Lfs*143 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- ACE2 | c.1863G>A p.R621= | Silent (SNP) | VAF 33/33 reads (100%) | catalogued as COSV53025233; called by muse, mutect2, varscan2
- ATP9B | c.1899C>T p.F633= | Silent (SNP) | VAF 64/124 reads (52%) | catalogued as COSV56951734; called by muse, mutect2, varscan2
- BRAF | c.468C>T p.I156= | Silent (SNP) | VAF 45/88 reads (51%) | catalogued as rs1562985327, COSV56191659; called by muse, varscan2
- BRMS1 | c.306G>A p.T102= | Silent (SNP) | VAF 31/59 reads (53%) | catalogued as rs1272215504, COSV60820164; called by muse, mutect2, varscan2
- BSN | c.8514G>A p.T2838= | Silent (SNP) | VAF 63/69 reads (91%) | catalogued as rs1345847635, COSV56518946; called by muse, mutect2, varscan2
- C2CD2 | c.1935C>G p.G645= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV61599565; called by muse, mutect2, varscan2
- CAMK1 | c.768G>A p.L256= | Silent (SNP) | VAF 84/182 reads (46%) | catalogued as COSV56538878; called by muse, mutect2, varscan2
- CDH1 | c.741G>A p.E247= | Silent (SNP) | VAF 68/152 reads (45%) | catalogued as COSV55733367; called by muse, mutect2, varscan2
- COL8A1 | c.939C>T p.P313= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs547121235, COSV53735026; called by muse, mutect2, varscan2
- DCAF12 | c.1353C>A p.L451= | Silent (SNP) | VAF 63/164 reads (38%) | catalogued as COSV63512616; called by muse, mutect2, varscan2
- DMXL1 | c.1875C>T p.L625= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV60712399; called by muse, mutect2, varscan2
- DNAH17 | c.1485C>A p.I495= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs775874131, COSV101103584; called by muse, mutect2, varscan2
- EHF | c.612G>C p.P204= | Silent (SNP) | VAF 41/87 reads (47%) | catalogued as COSV57668001, COSV57668160, COSV99140991; called by muse, mutect2, varscan2
- EXOC3 | c.1677G>A p.T559= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as rs369512321, COSV59266862; called by muse, mutect2, varscan2
- EXOSC4 | c.600G>A p.E200= | Silent (SNP) | VAF 53/111 reads (48%) | catalogued as COSV60155794; called by muse, mutect2, varscan2
- FAM135A | c.777C>T p.F259= (on ENST00000370479 / NM_001351599.1; = p.F216= on NM_020819.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV52051981; called by muse, mutect2, varscan2
- FANCM | c.3072C>A p.P1024= | Silent (SNP) | VAF 29/57 reads (51%) | catalogued as COSV57501536; called by muse, mutect2, varscan2
- FANCM | c.3570C>G p.L1190= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV57501546; called by muse, mutect2, varscan2
- GABRA1 | c.1047G>C p.V349= | Silent (SNP) | VAF 33/62 reads (53%) | catalogued as COSV50105386; called by muse, mutect2, varscan2
- GAK | c.1533G>C p.G511= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV100034109; called by muse, mutect2, varscan2
- GAS2L1 | c.159G>C p.L53= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV53330567; called by muse, varscan2
- GPRIN3 | c.1098G>A p.G366= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as COSV60885042; called by muse, mutect2, varscan2
- GSTM2 | c.141G>A p.L47= | Silent (SNP) | VAF 43/80 reads (54%) | catalogued as rs562313739, COSV53982603, COSV53984230; called by muse, mutect2, varscan2
- H2BC14 | c.222C>T p.I74= | Silent (SNP) | VAF 48/106 reads (45%) | catalogued as COSV60797768; called by muse, mutect2, varscan2
- HERC2 | c.4074G>A p.E1358= | Silent (SNP) | VAF 20/21 reads (95%) | catalogued as COSV99876961; called by mutect2, varscan2
- HSPG2 | c.5889G>A p.E1963= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV65972046; called by muse, mutect2, varscan2
- HTRA4 | c.81C>G p.L27= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV56759513; called by muse, varscan2
- INPP5F | c.2277C>T p.I759= | Silent (SNP) | VAF 53/120 reads (44%) | catalogued as COSV62821514; called by muse, mutect2, varscan2
- INTS5 | c.1932C>T p.L644= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as COSV57951724; called by muse, mutect2, varscan2
- KCNG2 | c.288G>A p.P96= | Silent (SNP) | VAF 19/25 reads (76%) | catalogued as rs1194036383, COSV100302192, COSV60267996; called by muse, mutect2, varscan2
- KLHL25 | c.1212G>A p.P404= | Silent (SNP) | VAF 31/33 reads (94%) | catalogued as rs747512642, COSV61995191; called by muse, mutect2, varscan2
- KLHL6 | c.1842C>T p.I614= | Silent (SNP) | VAF 47/91 reads (52%) | catalogued as rs369666567; called by muse, mutect2, varscan2
- LOXL1 | c.555C>T p.V185= | Silent (SNP) | VAF 59/60 reads (98%) | catalogued as COSV56094482; called by muse, mutect2, varscan2
- LRRC41 | c.2415C>T p.F805= | Silent (SNP) | VAF 98/145 reads (68%) | catalogued as rs145793278; called by muse, mutect2, varscan2
- LY9 | c.972C>T p.I324= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV54434399; called by muse, mutect2, varscan2
- MAP3K9 | c.1029G>A p.L343= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as COSV67121474; called by muse, mutect2, varscan2
- MPIG6B | c.630C>T p.L210= (on ENST00000649779 / NM_138272.3; = p.L217= on NM_025260.4) | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as rs1266368981, COSV65389716; called by muse, mutect2, varscan2
- MROH5 | c.3471G>C p.L1157= | Silent (SNP) | VAF 25/52 reads (48%) | catalogued as COSV100267465; called by muse, mutect2, varscan2
- MYH4 | c.1332C>T p.T444= | Silent (SNP) | VAF 93/101 reads (92%) | catalogued as COSV55118838; called by muse, mutect2, varscan2
- MYO18B | c.492A>G p.S164= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV100125328; called by muse, mutect2
- NBAS | c.4078C>T p.L1360= | Silent (SNP) | VAF 55/58 reads (95%) | catalogued as COSV55722649; called by muse, mutect2, varscan2
- NCKAP1L | c.690C>T p.L230= | Silent (SNP) | VAF 88/173 reads (51%) | catalogued as COSV53207313; called by muse, mutect2, varscan2
- NLRP14 | c.1272G>A p.L424= | Silent (SNP) | VAF 70/143 reads (49%) | catalogued as COSV55067586; called by muse, mutect2, varscan2
- OPN3 | c.498G>A p.L166= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as rs371668029; called by muse, mutect2, varscan2
- OR10A3 | c.255C>G p.L85= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV62459542; called by muse, mutect2, varscan2
- PAPLN | c.313C>A p.R105= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as rs755902550, COSV53718275, COSV53721003; called by muse, mutect2, varscan2
- PARP6 | c.147G>A p.E49= | Silent (SNP) | VAF 23/28 reads (82%) | catalogued as COSV53003351; called by muse, mutect2, varscan2
- PELI2 | c.417C>T p.F139= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as rs780154504, COSV50711389; called by muse, mutect2, varscan2
- PLA2G3 | c.315G>A p.Q105= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as COSV53209835; called by muse, mutect2, varscan2
- POTEA | c.1203T>C p.S401= (on ENST00000519951 / NM_001005365.2; = p.S355= on NM_001002920.1) | Silent (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1956G>A p.V652= | Silent (SNP) | VAF 43/92 reads (47%) | catalogued as rs748293321, COSV53453081; called by muse, mutect2, varscan2
- PROX1 | c.486G>A p.L162= | Silent (SNP) | VAF 48/106 reads (45%) | catalogued as rs1435696085, COSV54779364; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1290G>C p.L430= (on ENST00000352766; = p.L351= on NM_181334.5) | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV100424312, COSV61233755; called by muse, mutect2, varscan2
- RAB3A | c.318C>T p.N106= | Silent (SNP) | VAF 60/124 reads (48%) | catalogued as rs1221105793, COSV55852270; called by muse, mutect2, varscan2
- SEPTIN5 | c.978G>A p.E326= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV63530652; called by muse, mutect2, varscan2
- SH2D4A | c.312G>C p.L104= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV56122742; called by muse, mutect2, varscan2
- SIRPA | c.1434C>G p.L478= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as COSV61538891, COSV61538930; called by muse, mutect2
- SLC35F3 | c.669C>T p.Y223= (on ENST00000366617 / NM_001300845.1; = p.Y292= on NM_173508.4) | Silent (SNP) | VAF 150/310 reads (48%) | catalogued as rs764578116, COSV64019873; called by muse, mutect2, varscan2
- SNX18 | c.1671G>A p.L557= | Silent (SNP) | VAF 44/101 reads (44%) | catalogued as COSV57989534; called by muse, mutect2, varscan2
- SYT12 | c.873C>T p.L291= | Silent (SNP) | VAF 49/91 reads (54%) | catalogued as rs769405384, COSV67354087; called by muse, mutect2, varscan2
- TAS1R3 | c.2016G>A p.L672= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as rs760225500, COSV59563620; called by muse, mutect2, varscan2
- TAS2R39 | c.258C>G p.L86= | Silent (SNP) | VAF 71/138 reads (51%) | catalogued as COSV71470891; called by muse, mutect2, varscan2
- TMPRSS12 | c.657C>T p.N219= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as rs372309874; called by muse, mutect2, varscan2
- TNFRSF10C | c.777T>C p.V259= | Silent (SNP) | VAF 60/138 reads (43%) | catalogued as rs762137895, COSV63511732; called by muse, mutect2, varscan2
- TP53INP2 | c.6C>T p.F2= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as rs373986278, COSV100873713; called by muse, varscan2
- TTC23L | c.375G>T p.L125= | Silent (SNP) | VAF 50/118 reads (42%) | catalogued as COSV72205902; called by muse, mutect2, varscan2
- UBE4B | c.813C>G p.L271= | Silent (SNP) | VAF 59/93 reads (63%) | catalogued as COSV53533145; called by muse, mutect2, varscan2
- USP35 | c.2418C>T p.L806= | Silent (SNP) | VAF 54/118 reads (46%) | catalogued as COSV71572851; called by muse, mutect2, varscan2
- UTRN | c.4561C>T p.L1521= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV62336258; called by muse, mutect2, varscan2
- ZBBX | c.1449C>T p.I483= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs751732507, COSV56790252; called by muse, mutect2, varscan2
- ZBED4 | c.2451G>A p.L817= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV53465524; called by muse, mutect2, varscan2
- ZNF41 | c.924C>T p.F308= | Silent (SNP) | VAF 66/69 reads (96%) | catalogued as COSV57442751; called by muse, mutect2, varscan2
- ZNF606 | c.141G>A p.G47= | Silent (SNP) | VAF 40/93 reads (43%) | catalogued as COSV58350583; called by muse, mutect2, varscan2
- ZNF836 | c.1437C>T p.F479= | Silent (SNP) | VAF 53/106 reads (50%) | catalogued as COSV59083465; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504279 G>A | 5'Flank (SNP) | VAF 18/33 reads (55%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65505085 G>C | 5'Flank (SNP) | VAF 39/73 reads (53%) | called by muse, mutect2, varscan2
- CDIPT | c.-1G>A | 5'UTR (SNP) | VAF 44/112 reads (39%) | catalogued as rs1319092114, COSV99570291; called by muse, mutect2, varscan2
- DNMT3A | c.640-1464G>C | Intron (SNP) | VAF 50/52 reads (96%) | catalogued as COSV53054119; called by muse, mutect2, varscan2
- HNF4A | c.1129+80C>T | Intron (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100291747; called by muse, mutect2, varscan2
- NACA | c.71-1719G>C | Intron (SNP) | VAF 167/339 reads (49%) | catalogued as COSV63270133; called by muse, mutect2, varscan2
- NUTM2D | chr10:87367352 C>G | 3'Flank (SNP) | VAF 13/47 reads (28%) | catalogued as rs761880369, COSV67746203; called by muse, mutect2, varscan2
- P3H1 | c.2056-154C>A | Intron (SNP) | VAF 39/119 reads (33%) | catalogued as COSV99355629; called by muse, mutect2, varscan2
- PDPN | c.-165G>A | 5'UTR (SNP) | VAF 50/101 reads (50%) | catalogued as COSV53848388; called by muse, mutect2
- PKD2L2 | c.*18-2261dup | Intron (INS) | VAF 32/76 reads (42%) | called by mutect2, pindel, varscan2
- PRR12 | chr19:49594532 C>A | 5'Flank (SNP) | VAF 49/104 reads (47%) | catalogued as COSV99882213, COSV99882574; called by muse, mutect2, varscan2
